Gene-level copy-number profile of tumor specimen HCM-BROD-0614-C71-01A from HCMI case HCM-BROD-0614-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.3 years (23,138 days).
Specimen HCM-BROD-0614-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 39736e57-a574-4dd5-a23e-8e62df97cec7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0614-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/8a7d40a0-26d6-435b-825f-38016bb93591

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 100; copy number 1: 2; copy number 2: 5,906; copy number 3: 143; copy number 4: 45,552; copy number 5: 1,498; copy number 6: 4,962; copy number 7: 239.

Homozygous deletions (total copy number 0; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,705,338–26,118,408, 92 genes (within-gene range 0–2) (broad region; genes not listed).
- chr10:47,908,064–48,119,455, 8 genes: AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
